TARGET case TARGET-10-PANLGK — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c0fcb38b-2cd1-48fd-8f72-d865ee531d1c

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 1.0 years (365 days); Year of diagnosis: 2005; Days to last follow up: 2,597 days (7.1 years).
   Treatment given: Protocol identifier: P9407.

Follow-up (1 entry)
- Days to follow up: 2,597 days (7.1 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,597; Year of follow up: 2012.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 125 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-10-PANLGK-03A, TARGET-10-PANLGK-03B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PANLGK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Dicentric_20230727.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2597
- WBC at Diagnosis: 124.9
- CNS Status at Diagnosis: CNS 1
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- Karyotype: 45,XX,del(6)(q15q23),dic(7;9)(p11.2;p11),-13,del(20)(q11.2q13.1),+mar[15]/46,XX[8]
- DNA Index: 1
- Cell of Origin: B-Precursor
